Gene-level copy-number profile of tumor specimen TCGA-NJ-A4YF-01A from TCGA case TCGA-NJ-A4YF, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 50.9 years (18,584 days).
Specimen TCGA-NJ-A4YF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.5d522855-6f7e-47e7-bd50-408c094d8afd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-NJ-A4YF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/81be5a24-e5b6-4694-89cb-38932b5c2355

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,048; copy number 2: 22,598; copy number 3: 17,256; copy number 4: 11,683; copy number 5: 3,618; copy number 6: 1,048; copy number 7: 755; copy number 8: 170; copy number 9: 1,102; copy number 10: 64; copy number 11: 394; copy number 12: 66; copy number 15: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-NJ-A4YF-01A-12D-A25M-01): tumor purity 0.55, ploidy 3.21, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7,221 genes in 44 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–163,769,691, 886 genes, copy number 5 (broad region; genes not listed).
- chr1:238,476,542–248,919,946, 256 genes, copy number 5 (broad region; genes not listed).
- chr2:158,847,619–158,935,985, 5 genes, copy number 6: AC064843.1, OR7E89P, OR7E28P, OR7E90P, RNU2-21P.
- chr2:159,003,975–159,004,320, 1 gene, copy number 6: BTF3L4P2.
- chr3:88,601,061–93,843,862, 14 genes, copy number 7: NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P, HSPE1P19, ABBA01000933.1, ABBA01000935.2, RNU6-488P.
- chr3:166,160,021–193,593,111, 459 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr3:194,247,638–198,222,513, 150 genes, copy number 6 (broad region; genes not listed).
- chr4:25,472,517–25,679,020, 7 genes, copy number 6: AC133963.2, AC133963.1, AC105290.1, RNU7-126P, AC092436.1, SLC34A2, RPS29P11.
- chr4:40,990,154–59,180,414, 257 genes, copy number 5–6 (broad region; genes not listed).
- chr5:58,198–3,601,403, 92 genes, copy number 5 (broad region; genes not listed).
- chr5:4,451,930–45,895,970, 614 genes, copy number 5–15 (within-gene range 4–15) (broad region; genes not listed).
- chr5:137,617,500–138,935,034, 38 genes, copy number 5 (within-gene range 1–5): KLHL3, MIR874, HNRNPA0, AC106791.3, AC106791.2, NPY6R, AC106791.1, MYOT, PKD2L2, FAM13B, AC113382.1, AC113382.2, RNU6-1148P, WNT8A, NME5, RNU6-460P, RNU6-888P, BRD8, KIF20A, CDC23, GFRA3, RPS27AP18, CDC25C, FAM53C, AC104116.1, KDM3B, REEP2, AC113403.1, EGR1, RPL7P19, ETF1, HSPA9, SNORD63B, SNORD63, CTNNA1, AC113340.1, AC113340.2, AC034243.1.
- chr6:110,424,687–110,598,705, 5 genes, copy number 5 (within-gene range 2–5): SLC22A16, RN7SL617P, AC002464.1, AL512430.3, AL512430.4.
- chr7:2,251,770–3,302,452, 23 genes, copy number 5: SNX8, MIR6836, IMMP1LP3, EIF3B, AC004840.1, AC004840.2, CHST12, GRIFIN, LFNG, MIR4648, BRAT1, IQCE, TTYH3, AMZ1, GNA12, AC006028.1, CARD11, CARD11-AS1, RN7SKP130, AC024028.1, AC073316.1, AC073316.2, SDK1-AS1.
- chr7:3,337,889–3,643,784, 2 genes, copy number 5: AC092427.1, AC011284.1.
- chr8:37,067,441–145,066,685, 1,706 genes, copy number 7–11 (broad region; genes not listed).
- chr9:106,584,142–114,056,591, 136 genes, copy number 5–9 (within-gene range 4–9) (broad region; genes not listed).
- chr9:115,019,575–121,223,014, 51 genes, copy number 5–8 (within-gene range 1–8): TNC, AL162425.1, AL355601.1, AL691420.1, U2, LINC00474, AL691426.1, PAPPA, PAPPA-AS2, AL137024.1, PAPPA-AS1, ASTN2, ASTN2-AS1, AL133284.1, TRIM32, AL157829.1, RPL10P3, SNORA70C, RN7SKP128, RN7SKP125, AL445644.1, AL161630.1, RPL35AP22, AL160272.2, TLR4, RNU6-1082P, AL160272.1, AL354754.1, TPT1P9, AL355592.1, LINC02578, TUBB4BP6, BRINP1, AC006288.1, LINC01613, AL441989.1, MIR147A, CDK5RAP2, MEGF9, AHCYP2, FBXW2, B3GNT10, AL161911.1, PSMD5, CUTALP, PHF19, TRAF1, C5, CNTRL, RAB14, RN7SL181P.
- chr9:136,612,024–138,203,325, 109 genes, copy number 5 (broad region; genes not listed).
- chr10:44,712–46,131,358, 795 genes, copy number 5–8 (broad region; genes not listed).
- chr10:112,149,865–116,583,317, 68 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr10:128,912,810–129,380,753, 5 genes, copy number 6: LINC02667, AL355537.1, AL355537.2, AL391869.1, AL359508.1.
- chr11:67,119,263–92,915,644, 629 genes, copy number 5–9 (within-gene range 4–9) (broad region; genes not listed).
- chr11:100,336,856–102,903,953, 47 genes, copy number 5: RPA2P3, RN7SL222P, PPIAP43, ARHGAP42-AS1, ARHGAP42, RN7SKP115, PGR, PGR-AS1, AP001533.1, TRPC6, MIR3920, AP003080.1, AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2, MMP3, MMP12, BOLA3P1, RNU7-159P.
- chr11:105,974,826–109,823,893, 55 genes, copy number 5: RNU6-277P, AP000813.1, MSANTD4, KBTBD3, AASDHPPT, AP001001.1, AP001001.2, LINC02719, AP002001.3, AP002001.1, AP002001.2, AP003173.1, GUCY1A2, AP001282.2, AP001282.1, ASS1P13, AP000766.1, CWF19L2, SMARCE1P1, ALKBH8, AP001823.1, ELMOD1, AP000889.2, AP000889.1, SLN, AP002353.1, SLC35F2, AP001024.1, RAB39A, AP003307.1, CUL5, Y_RNA, AP002433.1, ACAT1, AP002433.2, NPAT, ATM, Y_RNA, C11orf65, POGLUT3, EXPH5, DDX10, RPS2P39, AP002453.1, CYCSP29, AP003027.1, AP003123.1, RNU6-654P, RNA5SP349, SNORD39, AP003049.2, C11orf87, AP003049.1, AP003102.1, LINC02715.
- chr11:109,907,004–109,907,741, 1 gene, copy number 5: TFAMP2.
- chr12:130,337,887–130,716,281, 8 genes, copy number 6 (within-gene range 3–6): PIWIL1, AC127071.2, AC127071.3, RIMBP2, AC063926.1, AC063926.3, AC063926.2, AC095350.1.
- chr14:22,007,512–22,509,406, 72 genes, copy number 5 (broad region; genes not listed).
- chr15:76,931,738–77,420,144, 11 genes, copy number 6 (within-gene range 3–6): RCN2, RN7SL278P, KRT8P23, PSTPIP1, TSPAN3, AC090181.1, AC090181.3, AC090181.2, PEAK1, AC087465.1, AC060773.1.
- chr16:21,401,089–22,613,483, 47 genes, copy number 7: AC008740.2, NPIPB3, SMG1P3, MIR3680-1, AC005632.6, SLC7A5P2, AC005632.5, AC005632.2, AC005632.4, AC005632.1, METTL9, AC005632.3, IGSF6, RNU6-1005P, RNU6-196P, OTOA, AC092375.2, RRN3P1, AC092375.3, NPIPB4, SMG1P4, AC092375.1, AC092119.2, UQCRC2, PDZD9, AC092119.1, AC092119.3, MOSMO, AC009019.1, VWA3A, SDR42E2, AC009019.2, EEF2K, AC009034.1, POLR3E, AC092338.3, CDR2, AC092338.1, AC092338.2, MFSD13B, RRN3P3, SMG1P1, NPIPB5, AC106788.1, OTOAP1, AC009021.2, AC009021.1.
- chr16:23,061,406–23,677,472, 23 genes, copy number 6: AC127459.1, USP31, AC127459.3, AC099482.2, SCNN1G, AC099482.1, SCNN1B, COG7, RN7SKP23, SNORA75, AC008915.1, AC008915.2, GGA2, CCNYL7, EARS2, SUB1P4, UBFD1, AC008870.2, NDUFAB1, PALB2, AC008870.4, DCTN5, AC008870.1.
- chr16:27,224,994–28,063,714, 15 genes, copy number 6 (within-gene range 2–6): NSMCE1, NSMCE1-DT, AC106739.1, IL4R, IL21R, IL21R-AS1, GTF3C1, KATNIP, AC002551.1, AC016597.1, AC016597.2, Y_RNA, GSG1L, RNU6-159P, RNU6-1241P.
- chr16:74,671,855–74,843,883, 3 genes, copy number 5 (within-gene range 3–5): MLKL, FA2H, AC009132.1.
- chr17:38,419,280–38,512,385, 2 genes, copy number 7 (within-gene range 3–7): ARHGAP23, AC244153.1.
- chr18:7,231,125–14,054,761, 178 genes, copy number 5–10 (broad region; genes not listed).
- chr18:26,204,869–26,438,041, 7 genes, copy number 7: NPM1P2, TAF4B, SINHCAFP1, AC121320.1, AC022069.1, RNU6-1289P, LINC01543.
- chr18:30,290,161–30,780,424, 4 genes, copy number 6: AC115100.1, MIR302F, AC090506.1, AC090506.2.
- chr18:31,101,583–33,441,101, 53 genes, copy number 8 (within-gene range 4–8): DSCAS, DSC1, AC012417.1, DSG1, DSG1-AS1, RNU6-167P, DSG4, Y_RNA, DSG3, AC021549.1, DSG2, DSG2-AS1, TTR, B4GALT6, AC017100.1, RN7SKP44, LRRC37A7P, AC017100.2, SLC25A52, TRAPPC8, AC022960.1, AC022960.3, AC022960.2, RNU6-1050P, AC009831.1, PGDP1, AC009831.2, AC009831.4, RNF125, AC011825.3, AC009831.3, AC011825.1, AC011825.4, RNF138, AC011825.2, GAREM1, RNA5SP453, MEP1B, CLUHP6, AC015563.1, Y_RNA, AC015563.2, HNRNPA1P7, AC025887.2, WBP11P1, AC009835.1, AC025887.1, KLHL14, AC012123.1, AC012123.2, AC090371.2, CCDC178, AC090371.1.
- chr20:38,033,725–38,383,179, 13 genes, copy number 7 (within-gene range 4–7): RPRD1B, RN7SL237P, AL031651.1, TGM2, KIAA1755, AL031651.2, AL359555.3, AL359555.4, AL359555.2, AL359555.1, BPI, LBP, AL391095.2.
- chr20:49,219,295–64,313,132, 370 genes, copy number 7–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,048. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
